Surgical pathology report (de-identified scan), TCGA case TCGA-UW-A7GL, project TCGA-KICH (Kidney Chromophobe), tissue source site University of North Carolina, specimen TCGA-UW-A7GL-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report

Diagnosis:

Kidney and adrenal gland, left, radical nephrectomy.

- Renal cell carcinoma, chromophobe type.
- Fuhrman nuclear grade: 3.
- Tumor size: 8 cm.
- Extent of invasion: Confined to kidney, encapsulated.
- Angiolymphatic and perineural invasion: Absent.
- Adrenal gland: Negative.
- Margins: Negative.

Clinical History:

year-old male with a history of head and neck cancer and now with a left renal mass.

Gross Description:

Received is one appropriately labeled container.

Specimen A additionally labeled "renal mass". The specimen consists of a nodular kidney with a large firm nodule in the upper pole, adrenal gland and perinephric fat. The posterior half of the kidney is inked blue, anterior half black, adrenal gland yellow, and hilar margin red.

Specimen fixation: Formalin

Type of specimen: Radical nephrectomy

Side of specimen: Left

Size and weight of specimen: 550 grams, 15 x 9 x 8 cm
with an attached 3 x 1.5 x 1 cm adrenal gland

Presence/absence of adrenal gland: Present

Tumor description/site: Tumor is a lobulated tan firm mass located in the upper pole of the kidney and involving both medulla and cortex in this pole. The cut surface of the tumor is tan and pink and glistening. There are no areas of necrosis, hemorrhage, cysts or calcification.

Tumor size: 8 x 7.5 x 7 cm

Presence/absence of multicentricity: Absent

ICD-O-3
Carcinoma, renal cell
Chromophobe type 8317/3
Site (L) Kidney NOS C64.9
JW 9/24/13

[page 2 of 3]
Confinement/non-confinement to the kidney: The tumor is fairly well circumscribed and seems to be confined to the kidney, but extends the capsule in the upper pole far beyond the normal kidney parenchyma. There is one area on the posterior side where it is possible the tumor has broken through the tumor capsule.

Extent of invasion:

Perirenal adipose tissue: Tumor does not grossly involve

Gerota's fascia: Tumor does not grossly involve

Renal vein: Tumor does not grossly involve

Ureter: Tumor does not grossly involve

Other organs: The tumor approaches but does not grossly involve the adrenal gland

Surgical margins:

Perirenal adipose tissue Grossly negative

Renal vein: Grossly negative

Renal artery: Grossly negative

Ureter: Grossly negative

Description of kidney away from tumor: Renal parenchyma away from tumor is pink and glistening with what appears to be an expanded cortex measuring from 0.6 to 1.0 cm, a medulla of 1.5 cm, and a distinct cortical medullary junction.

Lymph nodes (hilar): The perihilar fat is palpated for lymph nodes but none are appreciated

Block Summary:

A1 - Surgical margins of ureter and hilum

A2 - Tumor at its closest approximation to kidney capsule/Gerota's fascia

A3 - Tumor and adrenal gland

A4 - Tumor and suspicious yellow mass near adrenal gland

A5 - Tumor and normal kidney

A6-A8 - Representative sections of tumor (A6 is taken from the anterior portion of the tumor, A7-A8 from the posterior portion of tumor)

A9 - Normal kidney parenchyma

Light Microscopy:

Light microscopic examination is performed by Dr.

Histologic tumor type/subtype: renal cell carcinoma, chromophobe

Histologic grade (if applicable): 3 of 4

Tumor size (greatest dimension): 8 cm

[page 3 of 3]
Extent of tumor invasion:

Capsular invasion/perirenal adipose tissue: negative

Gerota's fascia: negative

Renal vein: negative

Ureter: negative

Venous (large vessel): negative

Lymphatic (small vessel): negative

Histologic assessment of surgical margins:

Perirenal adipose tissue: negative

Gerota's fascia: negative

Renal vein: negative

Renal artery: negative

Ureter: negative

Adrenal gland: negative for tumor

Lymph nodes: none identified

Other significant findings: none

AJCC Staging: pT2 pNX pMX

Source: NCI Genomic Data Commons file a80cc2b2-a8a1-4240-bae9-93e1315536d1 (TCGA-UW-A7GL.6DB2BA4C-7145-4E26-83AF-31DC13457C3F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).